Somatic mutation profile of tumor specimen TCGA-A4-8517-01A (aliquot TCGA-A4-8517-01A-11D-2396-08) from TCGA case TCGA-A4-8517, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 71.4 years (26,090 days).
Specimen TCGA-A4-8517-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a14f386d-8413-445b-bcee-f286ba0ada9b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-8517-10A (Blood Derived Normal), aliquot TCGA-A4-8517-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36156a22-f0e0-4cb8-a9fe-526ea47b324f

The open-access MAF lists 86 somatic variants for this specimen: 61 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 22, Frame Shift Del 9, Nonsense Mutation 3, Frame Shift Ins 2, Splice Region 2, Splice Site 1, In Frame Del 1, RNA 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFDN | c.3761A>T p.E1254V | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.179); catalogued as COSV60050381; called by muse, mutect2, varscan2
- AHCYL1 | c.1219-1G>A p.X407_splice | Splice Site (SNP) | VAF 15/35 reads (43%) | catalogued as COSV63209119; called by muse, mutect2, varscan2
- ARFGEF2 | c.3916C>A p.R1306= | Splice Region (SNP) | VAF 57/101 reads (56%) | catalogued as COSV64213846; called by muse, mutect2, varscan2
- ASAP2 | c.1727T>C p.I576T | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55635503; called by muse, mutect2, varscan2
- BDP1 | c.4943T>A p.V1648E | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV62432935; called by muse, mutect2, varscan2
- CAP1 | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61223965; called by muse, mutect2, varscan2
- CCS | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs149989199; called by muse, mutect2, varscan2
- CDH26 | c.1666G>C p.G556R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54850690; called by muse, mutect2, varscan2
- CLIP3 | c.858T>G p.N286K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.159); catalogued as COSV62113074; called by muse, mutect2, varscan2
- CPN2 | c.1234C>A p.Q412K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV60471136; called by muse, mutect2, varscan2
- CUL9 | c.770T>C p.F257S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV52731761; called by muse, mutect2, varscan2
- CYBC1 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.728); catalogued as rs142773924, COSV60064461; called by muse, mutect2, varscan2
- DDR1 | c.2045C>A p.P682Q (on ENST00000324771; = p.P645Q on NM_001954.4) | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61323114; called by muse, mutect2, varscan2
- DSCAML1 | c.4583A>G p.E1528G (on ENST00000321322; = p.E1468G on NM_020693.4) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58397350; called by muse, mutect2, varscan2
- GBF1 | c.4511A>G p.H1504R (on ENST00000369983 / NM_001377137.1; = p.H1503R on NM_004193.3) | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208474584, COSV64147222; called by muse, mutect2, varscan2
- HSPA14 | c.811T>A p.S271T | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV65684764; called by muse, mutect2, varscan2
- HYKK | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV64762269, COSV64762484, COSV64762591; called by muse, mutect2
- KIF3B | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.579); catalogued as COSV65228590; called by muse, mutect2, varscan2
- KIFC1 | c.150G>T p.K50N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV65737752; called by muse, mutect2, varscan2
- LRRC55 | c.295A>T p.N99Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73006773; called by muse, mutect2, varscan2
- LRRC55 | c.296A>C p.N99T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73006776; called by muse, mutect2, varscan2
- MFN1 | c.356A>C p.D119A | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV54941134; called by muse, mutect2, varscan2
- MRPL40 | c.591G>T p.K197N | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54277546, COSV54279671; called by muse, mutect2, varscan2
- NCAM2 | c.1903A>G p.K635E | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.994); catalogued as rs201923816, COSV53090234; called by muse, mutect2, varscan2
- NCLN | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs200277850; called by muse, mutect2, varscan2
- NOL3 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV50458388; called by muse, mutect2, varscan2
- NRDC | c.3280G>T p.E1094* | Nonsense Mutation (SNP) | VAF 25/57 reads (44%) | catalogued as COSV61406708; called by muse, mutect2, varscan2
- NUDT5 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.743); catalogued as COSV66718770; called by muse, mutect2, varscan2
- NXPE4 | c.992G>A p.S331N (on ENST00000375478 / NM_001077639.2; = p.S47N on NM_017678.3) | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV64944121; called by muse, mutect2, varscan2
- NXT2 | c.15G>A p.L5= (on ENST00000372106 / NM_001242617.2; = p.L60= on NM_018698.5) | Splice Region (SNP) | VAF 6/15 reads (40%) | catalogued as rs1471323048, COSV54297047; called by muse, mutect2
- ODAM | c.404T>A p.M135K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV68573214; called by muse, mutect2
- OR1L8 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV59186879; called by muse, mutect2, varscan2
- PGA3 | c.424A>G p.M142V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV100337323; called by mutect2, varscan2
- PKN1 | c.2356G>T p.V786L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52875894; called by muse, mutect2, varscan2
- PLEKHG1 | c.610T>G p.Y204D | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62049405; called by muse, mutect2, varscan2
- POLR3C | c.1564del p.L522Cfs*10 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | catalogued as COSV57907212; called by mutect2, pindel, varscan2
- PPIE | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs1557447168, COSV60972033; called by muse, mutect2, varscan2
- PYGB | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 149/253 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs139162483; called by muse, mutect2, varscan2
- RANBP2 | c.3514T>G p.F1172V | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51705135; called by muse, mutect2, varscan2
- RBM17 | c.1156T>C p.F386L | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200401715, COSV65913722, COSV65914498; called by muse, mutect2, varscan2
- SDC4 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV65595765, COSV65595933; called by muse, mutect2, varscan2
- SLC4A4 | c.3154A>G p.M1052V (on ENST00000264485 / NM_001098484.3; = p.M1008V on NM_003759.4) | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52622886; called by muse, mutect2, varscan2
- SMG1 | c.6039del p.M2014* | Frame Shift Del (DEL) | VAF 72/144 reads (50%) | catalogued as COSV67171972; called by mutect2, pindel, varscan2
- SYNE2 | c.16611T>A p.H5537Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV59960286; called by muse, mutect2, varscan2
- TCF23 | c.463A>T p.K155* | Nonsense Mutation (SNP) | VAF 99/245 reads (40%) | catalogued as COSV56078784; called by muse, mutect2, varscan2
- THOC2 | c.4023A>T p.K1341N | Missense Mutation (SNP) | VAF 54/63 reads (86%) | SIFT tolerated (0.09); PolyPhen benign (0.395); catalogued as COSV55551407; called by muse, mutect2, varscan2
- UBE3C | c.236T>A p.L79* | Nonsense Mutation (SNP) | VAF 42/148 reads (28%) | catalogued as COSV61954778; called by muse, mutect2, varscan2
- VCAN | c.7573A>T p.R2525W | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54111358; called by muse, mutect2, varscan2
- WWC1 | c.710A>C p.D237A | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV54655058; called by muse, mutect2, varscan2
- WWC3 | c.2067del p.Y689* | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | catalogued as COSV101081887; called by mutect2, pindel, varscan2
- ZFP69 | c.911G>T p.C304F | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65529336; called by muse, mutect2, varscan2
- ZNF709 | c.599A>C p.E200A | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.265); catalogued as COSV67195373; called by muse, mutect2, varscan2
- CEP63 | c.1161del p.E387Dfs*9 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- CHD8 | c.4020del p.I1341Sfs*43 (on ENST00000646647 / NM_001170629.2; = p.I1062Sfs*43 on NM_020920.4) | Frame Shift Del (DEL) | VAF 59/150 reads (39%) | called by mutect2, pindel, varscan2
- CHMP2A | c.468_469insA p.E157Rfs*5 | Frame Shift Ins (INS) | VAF 68/217 reads (31%) | called by mutect2, pindel, varscan2
- DDX58 | c.2077_2092del p.I693Qfs*27 | Frame Shift Del (DEL) | VAF 22/59 reads (37%) | called by mutect2, pindel, varscan2
- FBXO36 | c.253_255del p.N85del | In Frame Del (DEL) | VAF 40/108 reads (37%) | called by mutect2, pindel, varscan2
- PIP5K1C | c.899del p.K300Rfs*84 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- PRMT6 | c.924del p.T309Pfs*17 | Frame Shift Del (DEL) | VAF 34/88 reads (39%) | called by mutect2, pindel, varscan2
- SCAPER | c.3126_3127dup p.K1043Ifs*8 | Frame Shift Ins (INS) | VAF 30/87 reads (34%) | called by mutect2, pindel, varscan2
- SHROOM3 | c.2035del p.E679Sfs*2 | Frame Shift Del (DEL) | VAF 70/175 reads (40%) | called by mutect2, pindel, varscan2
- ADAD2 | c.642G>A p.A214= (on ENST00000315906 / NM_001145400.2; = p.A286= on NM_139174.4) | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs369199969, COSV51894430; called by muse, mutect2, varscan2
- ALDH3B1 | c.531A>T p.L177= | Silent (SNP) | VAF 78/189 reads (41%) | catalogued as COSV50289978; called by muse, mutect2, varscan2
- ARF3 | c.102A>G p.L34= | Silent (SNP) | VAF 94/283 reads (33%) | catalogued as rs778325471, COSV56741613; called by muse, mutect2, varscan2
- CELSR1 | c.7863T>C p.A2621= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as COSV53095174; called by muse, mutect2, varscan2
- COPA | c.282T>C p.D94= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV54106539; called by muse, mutect2, varscan2
- CPEB3 | c.450T>G p.T150= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV56460195; called by muse, mutect2, varscan2
- CUL9 | c.771C>T p.F257= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as rs776986537, COSV52731773; called by muse, mutect2, varscan2
- EXOSC9 | c.342G>A p.K114= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV54667099; called by muse, mutect2, varscan2
- FAM13C | c.162G>T p.L54= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV53252554; called by muse, mutect2, varscan2
- FBLN5 | c.801C>A p.G267= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV50906269; called by muse, mutect2, varscan2
- HYAL2 | c.330G>A p.R110= | Silent (SNP) | VAF 29/85 reads (34%) | catalogued as COSV51701070; called by muse, mutect2, varscan2
- KIF13B | c.2754G>A p.P918= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as rs768939426, COSV72954305; called by muse, mutect2, varscan2
- MIOX | c.360G>T p.G120= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV53313955; called by muse, mutect2, varscan2
- NOTCH3 | c.423C>A p.R141= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV54642173; called by muse, mutect2, varscan2
- OGDH | c.2850T>C p.N950= | Silent (SNP) | VAF 64/229 reads (28%) | catalogued as COSV56053976; called by muse, mutect2, varscan2
- RAB38 | c.114C>T p.Y38= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV54714407; called by muse, mutect2, varscan2
- SDC3 | c.1053C>A p.P351= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV59580012; called by muse, mutect2, varscan2
- SPTBN1 | c.1242C>T p.L414= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as rs756836467, COSV61691267; called by muse, mutect2, varscan2
- SPTLC1 | c.661C>T p.L221= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV52765490; called by muse, mutect2, varscan2
- TNIP1 | c.123G>C p.G41= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV59308848; called by muse, mutect2, varscan2
- USP13 | c.771C>A p.A257= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV55862472, COSV55868623; called by muse, mutect2, varscan2
- VPS39 | c.1164C>A p.P388= (on ENST00000348544 / NM_001301138.2; = p.P377= on NM_015289.5) | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV58791692; called by muse, mutect2, varscan2
- MROH8 | c.-226T>A | 5'UTR (SNP) | VAF 11/20 reads (55%) | catalogued as COSV54122565; called by muse, mutect2, varscan2
- SRSF6 | c.257-574G>A | Intron (SNP) | VAF 44/71 reads (62%) | called by muse, mutect2, varscan2
- SSPOP | n.8711C>A | RNA (SNP) | VAF 15/85 reads (18%) | catalogued as COSV65133854; called by muse, mutect2, varscan2
